Somatic mutation profile of tumor specimen TCGA-66-2755-01A (aliquot TCGA-66-2755-01A-01D-1522-08) from TCGA case TCGA-66-2755, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.9 years (23,348 days).
Specimen TCGA-66-2755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5a19624-f7e9-498f-8866-e53f1671a0a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2755-11A (Solid Tissue Normal), aliquot TCGA-66-2755-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f57580-5b2c-403f-9e31-791fbc1707ae

The open-access MAF lists 243 somatic variants for this specimen: 171 protein-altering or splice-affecting, 69 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 69, Nonsense Mutation 10, Splice Region 4, Frame Shift Ins 4, Splice Site 4, Frame Shift Del 3, Intron 2, Translation Start Site 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 42/299 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as CM162636, COSV55873442, COSV55926654, COSV55949642; called by muse, mutect2, varscan2
- PSPH | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs104894036, CM040258, COSV51910690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6418G>T p.A2140S | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58134557; called by muse, mutect2, varscan2
- ADAM32 | c.1545T>A p.F515L | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV65949274; called by muse, mutect2, varscan2
- AGTPBP1 | c.2872A>G p.M958V (on ENST00000357081 / NM_001330701.2; = p.M918V on NM_015239.2) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1564035628, COSV61271645; called by muse, mutect2, varscan2
- AJAP1 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV65450810; called by muse, mutect2, varscan2
- AKAP13 | c.3029A>C p.Q1010P | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV63457012; called by muse, mutect2, varscan2
- ALG13 | c.2542A>G p.I848V | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52638916; called by muse, mutect2, varscan2
- ANKRD26 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65794344; called by muse, mutect2
- ANXA7 | c.644G>A p.R215H (on ENST00000372919 / NM_001320880.2; = p.R193H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs770294831, COSV65823486; called by muse, mutect2, varscan2
- APOB | c.11339C>A p.A3780D | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.196); catalogued as COSV51935225; called by muse, mutect2, varscan2
- ASB5 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56670672; called by muse, mutect2, varscan2
- ASCL4 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV60816631; called by muse, mutect2, varscan2
- ATG14 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 47/140 reads (34%) | catalogued as COSV55956568; called by muse, mutect2, varscan2
- ATRNL1 | c.1183T>C p.W395R | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61804239; called by muse, mutect2, varscan2
- C21orf91 | c.887A>T p.N296I (on ENST00000284881 / NM_001100420.2; = p.N295I on NM_017447.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53032927; called by muse, mutect2, varscan2
- CACNA1I | c.5764C>G p.L1922V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV60808223; called by muse, mutect2, varscan2
- CCR5 | c.561T>A p.Y187* | Nonsense Mutation (SNP) | VAF 193/524 reads (37%) | catalogued as COSV52751651; called by muse, mutect2, varscan2
- CDKL4 | c.927+7C>A | Splice Region (SNP) | VAF 72/313 reads (23%) | catalogued as COSV66509571; called by muse, mutect2, varscan2
- CECR2 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836337; called by muse, mutect2, varscan2
- CHD7 | c.2581del p.A861Qfs*27 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV101418520; called by mutect2, pindel, varscan2
- CHD7 | c.6068G>T p.R2023M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs764358718, COSV71110418; called by muse, mutect2, varscan2
- CHGB | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV66760464; called by muse, mutect2, varscan2
- CHGB | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV66760470; called by muse, mutect2, varscan2
- CHORDC1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV57706022; called by muse, mutect2, varscan2
- CHRM2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57772332; called by muse, varscan2
- CHRM2 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57772340, COSV57776827; called by muse, mutect2, varscan2
- CHRNA9 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV59574478; called by muse, mutect2, varscan2
- COL5A1 | c.5041G>T p.V1681F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV65664604, COSV65668915; called by muse, mutect2, varscan2
- COL6A5 | c.6479C>T p.S2160L (on ENST00000312481; = p.S2156L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs768029912, COSV55201607; called by muse, mutect2, varscan2
- COL7A1 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as rs748854484, COSV60395226, COSV60404401; called by muse, varscan2
- CRLF2 | c.597C>G p.Y199* | Nonsense Mutation (SNP) | VAF 50/195 reads (26%) | catalogued as COSV101053561; called by muse, mutect2, varscan2
- CTC1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532695142, COSV59853290; called by muse, mutect2, varscan2
- CTNNA1 | c.1749C>T p.V583= | Splice Region (SNP) | VAF 21/63 reads (33%) | catalogued as rs1203628463, COSV57073864; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTNNA2 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV63558240; called by muse, mutect2, varscan2
- CTNNA2 | c.2121C>A p.S707R | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs780278071, COSV100562322, COSV58151912; called by muse, mutect2, varscan2
- DAAM2 | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51317694; called by muse, varscan2
- DAGLB | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51703938, COSV51706048; called by muse, mutect2, varscan2
- DMD | c.3310A>T p.S1104C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV63754927; called by muse, mutect2
- DNAH7 | c.10083G>T p.L3361F | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs769130593, COSV56759192, COSV56764876; called by muse, mutect2, varscan2
- DPP8 | c.1768A>T p.N590Y (on ENST00000341861 / NM_001320875.2; = p.N574Y on NM_017743.6) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55678712; called by muse, mutect2, varscan2
- DTL | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as rs756403889, COSV65342362; called by muse, mutect2, varscan2
- ELMOD3 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs143405971; called by muse, mutect2, varscan2
- ENPP3 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV62954221; called by muse, mutect2, varscan2
- EPB41 | c.2468C>T p.T823I (on ENST00000343067 / NM_001166005.2; = p.T547I on NM_004437.4) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766136287, COSV58046603; called by muse, mutect2, varscan2
- ESM1 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 338/1088 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.412); catalogued as COSV67318567; called by muse, mutect2, varscan2
- FAM133A | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV59075311; called by muse, mutect2, varscan2
- FAM153A | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV62362035; called by mutect2, varscan2
- FAM153B | c.695C>A p.S232Y (on ENST00000253490; = p.S155Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 42/439 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV53686440; called by muse, mutect2
- FAM161B | c.1286C>T p.P429L (on ENST00000651776; = p.P366L on NM_152445.3) | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54102181; called by muse, mutect2, varscan2
- FAM47A | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.909); catalogued as rs1408103342, COSV100649851, COSV60494256; called by muse, varscan2
- FOXA3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100141144; called by muse, mutect2, varscan2
- FRA10AC1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 93/420 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771692369, COSV63272011; called by muse, mutect2
- FSCB | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 116/433 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV61217989, COSV61219053; called by muse, mutect2, varscan2
- FSHR | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs771137333, COSV58623611; called by muse, mutect2
- GBP4 | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV63254289; called by muse, mutect2
- GCDH | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.368); catalogued as COSV55820120; called by muse, mutect2, varscan2
- GCNA | c.2024T>G p.V675G | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65461928; called by muse, mutect2, varscan2
- GET3 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV62002348; called by muse, mutect2, varscan2
- GPR142 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV59519354; called by muse, mutect2, varscan2
- GRAMD1B | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV59204194; called by muse, mutect2
- GRB14 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55738217; called by muse, mutect2, varscan2
- GRID1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60014973; called by muse, mutect2, varscan2
- GZMK | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 156/507 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV50245108, COSV99140891; called by muse, mutect2, varscan2
- HAO1 | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV66492000; called by muse, mutect2, varscan2
- HTR3B | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV52744585, COSV99492050; called by muse, mutect2, varscan2
- IGFN1 | c.3573C>A p.F1191L (on ENST00000295591 / NM_001367841.1; = p.F3648L on NM_001164586.2) | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV55172527; called by muse, mutect2, varscan2
- IL1RAP | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV50761480; called by muse, mutect2, varscan2
- IQGAP2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1326314501, COSV57173399; called by muse, mutect2, varscan2
- IQUB | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61239249; called by muse, mutect2, varscan2
- ITPRID1 | c.2915G>A p.C972Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60074662; called by muse, mutect2, varscan2
- KDM1B | c.1902G>T p.Q634H (on ENST00000449850; = p.Q401H on NM_153042.4) | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52810733; called by muse, mutect2
- KDM5C | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV62891022; called by muse, mutect2, varscan2
- KRT71 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs766135554, COSV57290542; called by muse, mutect2
- KRTAP21-2 | c.70G>T p.G24* | Nonsense Mutation (SNP) | VAF 45/113 reads (40%) | catalogued as COSV61684156; called by muse, mutect2, varscan2
- LDHB | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV63364722; called by muse, mutect2, varscan2
- LRP1B | c.10723C>A p.H3575N | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV67219891; called by muse, varscan2
- LRP1B | c.9412G>A p.D3138N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67188414, COSV67219902; called by muse, mutect2
- LRP2 | c.13936G>A p.A4646T | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202210831, COSV55553055; called by muse, mutect2, varscan2
- LRP3 | c.1676A>T p.Q559L | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53503970; called by muse, mutect2, varscan2
- LRRC30 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV67301723; called by muse, mutect2, varscan2
- LRRC30 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV67301623; called by muse, mutect2, varscan2
- LTBP1 | c.1237T>A p.C413S (on ENST00000404816 / NM_206943.4; = p.C87S on NM_000627.4) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV63186925; called by muse, mutect2
- MAG | c.1617-2A>G p.X539_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV62700561; called by muse, mutect2, varscan2
- MAGEB2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV66780739; called by muse, mutect2, varscan2
- MAGI2 | c.2887G>C p.A963P | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62659275; called by muse, mutect2, varscan2
- MAP7 | c.1530A>C p.Q510H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV63419650; called by muse, mutect2, varscan2
- MBD6 | c.2085C>T p.P695= | Splice Region (SNP) | VAF 53/208 reads (25%) | catalogued as COSV63074538; called by muse, mutect2, varscan2
- MMRN1 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV53337402; called by muse, mutect2, varscan2
- MYBPC3 | c.1976T>C p.I659T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs397515941, CM1410886, COSV57027520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV3 | c.109T>G p.C37G | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57079623; called by muse, mutect2, varscan2
- NIPAL4 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57430062; called by muse, mutect2, varscan2
- NLRP5 | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66762001, COSV66764507; called by muse, mutect2, varscan2
- NMBR | c.423-2A>G p.X141_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | catalogued as COSV57801190; called by muse, mutect2
- NOA1 | c.602A>T p.Y201F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV51736982; called by muse, mutect2, varscan2
- NR1H4 | c.28C>A p.H10N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58094918; called by muse, mutect2, varscan2
- NR2E1 | c.739+2T>A p.X247_splice | Splice Site (SNP) | VAF 35/203 reads (17%) | catalogued as COSV64561959; called by muse, mutect2, varscan2
- OR11H12 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1376149513, COSV73543692; called by muse, mutect2, varscan2
- OR1J4 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61589800; called by muse, mutect2, varscan2
- OR4D9 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 106/494 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61434441, COSV61434695; called by muse, mutect2, varscan2
- OR5H1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63402183, COSV63402357; called by muse, mutect2, varscan2
- PAPPA2 | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 167/337 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV62778150, COSV62778844; called by muse, mutect2, varscan2
- PAPPA2 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 91/167 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746443344, COSV62778158; called by muse, mutect2, varscan2
- PEAK3 | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV59701412, COSV59701806; called by muse, mutect2, varscan2
- PLA2G4C | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62785492; called by muse, mutect2, varscan2
- PLCL2 | c.1776G>T p.M592I (on ENST00000615277 / NM_001144382.2; = p.M466I on NM_015184.5) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV67622100; called by muse, mutect2, varscan2
- PLS1 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 45/505 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV61833822; called by muse, mutect2
- POPDC3 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54644121; called by muse, mutect2, varscan2
- POTEE | c.2728C>G p.R910G | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV58223549, COSV58230656; called by muse, mutect2, varscan2
- POTEF | c.2508C>G p.I836M | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.989); catalogued as rs1356473172, COSV62541283; called by muse, varscan2
- PPP1R16B | c.696G>T p.L232= | Splice Region (SNP) | VAF 18/133 reads (14%) | catalogued as COSV55377700; called by muse, mutect2, varscan2
- PPP1R16B | c.696+1G>T p.X232_splice | Splice Site (SNP) | VAF 17/130 reads (13%) | catalogued as COSV55377120, COSV55377709; called by muse, mutect2, varscan2
- PRAMEF2 | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV53575405, COSV53579976; called by muse, mutect2, varscan2
- PRKDC | c.6061G>T p.G2021C | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs541975682, COSV58052261; called by muse, mutect2, varscan2
- PRPS1L1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 162/558 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV72649857, COSV72649895; called by muse, mutect2, varscan2
- PRR23B | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as rs376706999, COSV61494856; called by muse, mutect2
- PRSS37 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV63339422; called by muse, mutect2, varscan2
- PTGR1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV53028771; called by muse, mutect2, varscan2
- PTPRZ1 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66436501; called by muse, mutect2, varscan2
- RYR2 | c.5149G>T p.A1717S | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs547829995, COSV63685492; called by muse, mutect2, varscan2
- RYR3 | c.2752T>A p.Y918N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66789172; called by muse, mutect2, varscan2
- SACS | c.3518G>C p.W1173S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV66539841; called by muse, mutect2, varscan2
- SAFB2 | c.2858A>T p.Y953F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV53042453; called by muse, mutect2, varscan2
- SCG3 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV55021042, COSV55021257, COSV99591009; called by muse, mutect2, varscan2
- SCN1A | c.5510C>A p.P1837Q (on ENST00000303395 / NM_001202435.3; = p.P1826Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV57669951; called by muse, mutect2, varscan2
- SEC24D | c.2693A>G p.K898R | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs764869843, COSV54879762; called by muse, mutect2, varscan2
- SERPINA7 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV59665794, COSV59667041; called by muse, mutect2, varscan2
- SGMS2 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as COSV62989279; called by muse, mutect2, varscan2
- SIPA1L2 | c.3817A>G p.M1273V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1312452955, COSV53390418; called by muse, mutect2
- SIRPG | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99403298; called by muse, mutect2, varscan2
- SLC22A2 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV65266459; called by muse, mutect2
- SLC22A9 | c.1408A>G p.M470V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs759896529, COSV54167189; called by muse, mutect2, varscan2
- SLC7A1 | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.67); catalogued as COSV66330543; called by muse, mutect2
- SLC9B1 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV56470124; called by muse, mutect2
- SLCO5A1 | c.2148G>T p.W716C | Missense Mutation (SNP) | VAF 33/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866014907, COSV52659416; called by muse, mutect2
- SLITRK3 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 181/549 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53848453; called by muse, mutect2, varscan2
- SNX15 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV57246920; called by muse, mutect2, varscan2
- SORCS1 | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as COSV53866327; called by muse, mutect2, varscan2
- SPAG17 | c.5449G>A p.A1817T | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60458770; called by muse, mutect2, varscan2
- SPAST | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59514481; called by muse, mutect2, varscan2
- SPEF2 | c.3036G>T p.W1012C | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775017946, COSV61548290; called by muse, mutect2, varscan2
- SPINK5 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs747056451, COSV56253907; called by muse, mutect2, varscan2
- SPINK5 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV56253926; called by muse, mutect2, varscan2
- SPTA1 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV63753008; called by muse, mutect2, varscan2
- STX7 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 64/305 reads (21%) | catalogued as COSV63398729; called by muse, mutect2, varscan2
- SV2B | c.1384A>T p.M462L | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV57699734; called by muse, mutect2, varscan2
- SYNE2 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV58360751; called by muse, mutect2
- TBC1D7 | c.882A>G p.*294Wext*26 | Nonstop Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as COSV58244038; called by muse, mutect2, varscan2
- TLR3 | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as COSV57168572; called by muse, mutect2, varscan2
- TMX3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1280900418, COSV55185436; called by muse, mutect2, varscan2
- TNFRSF13B | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV55427759; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2681T>G p.L894R | Missense Mutation (SNP) | VAF 116/449 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV64101056; called by muse, mutect2, varscan2
- TRAF1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as COSV65868093; called by muse, mutect2, varscan2
- TTC21B | c.3866G>C p.C1289S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV54630578; called by muse, mutect2, varscan2
- USP13 | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.155); catalogued as COSV55865719; called by muse, mutect2
- VN1R2 | c.881A>C p.Q294P | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59038252; called by muse, mutect2, varscan2
- ZFHX4 | c.4114G>T p.D1372Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV50795888, COSV99266657; called by muse, mutect2, varscan2
- ZFP30 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV63622575; called by muse, mutect2, varscan2
- ZNF184 | c.1237A>G p.T413A | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV53004297; called by muse, mutect2, varscan2
- ZNF407 | c.2235C>A p.S745R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55253032; called by muse, mutect2, varscan2
- ZNF536 | c.2857G>T p.D953Y | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV62824207; called by muse, mutect2, varscan2
- ZNF804B | c.3775C>A p.H1259N | Missense Mutation (SNP) | VAF 143/469 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV60827890; called by muse, mutect2, varscan2
- ADCY2 | c.2823dup p.G942Wfs*61 | Frame Shift Ins (INS) | VAF 41/128 reads (32%) | called by mutect2, pindel, varscan2
- DBR1 | c.248del p.G83Efs*25 | Frame Shift Del (DEL) | VAF 115/507 reads (23%) | called by mutect2, pindel, varscan2
- DMRTC1 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HEATR9 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPPL1 | c.2938dup p.S980Kfs*4 | Frame Shift Ins (INS) | VAF 39/226 reads (17%) | called by mutect2, varscan2
- INPPL1 | c.2939delinsAT p.S980Nfs*4 | Frame Shift Ins (INS) | VAF 33/264 reads (13%) | called by mutect2*, pindel, varscan2*
- LMO3 | c.156del p.T53Pfs*16 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.1411C>A p.H471N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, varscan2
- REG1A | c.480dup p.V161Cfs*45 | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- ABCA13 | c.9063T>G p.T3021= | Silent (SNP) | VAF 119/371 reads (32%) | catalogued as COSV71287765; called by muse, mutect2, varscan2
- ABCC12 | c.3015C>G p.G1005= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV60913899; called by muse, mutect2, varscan2
- AHNAK2 | c.9762C>T p.D3254= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as COSV60915319, COSV60924656; called by muse, mutect2
- AHNAK2 | c.9267C>T p.D3089= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV60915324, COSV60924663; called by muse, mutect2, varscan2
- AHRR | c.741G>T p.L247= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV57086102; called by muse, mutect2, varscan2
- ARAP2 | c.1110A>C p.T370= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV58286700; called by muse, mutect2, varscan2
- BBX | c.1752A>G p.L584= | Silent (SNP) | VAF 14/185 reads (8%) | catalogued as COSV57884498; called by muse, mutect2
- CALCOCO1 | c.177G>T p.R59= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV50414100; called by muse, mutect2, varscan2
- CCNB3 | c.720G>C p.R240= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV52073616; called by muse, mutect2, varscan2
- CDH9 | c.1296T>C p.G432= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as COSV50285601; called by muse, mutect2
- CILP2 | c.2811G>T p.R937= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV52274977; called by muse, mutect2, varscan2
- CLPTM1L | c.531C>T p.N177= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs1186803024, COSV57990496; called by muse, mutect2, varscan2
- COQ10B | c.576A>G p.L192= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV55836343; called by muse, mutect2, varscan2
- CPED1 | c.2733G>A p.Q911= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV60002253; called by muse, mutect2, varscan2
- DCST1 | c.231A>G p.E77= | Silent (SNP) | VAF 143/278 reads (51%) | catalogued as COSV55051797; called by muse, mutect2, varscan2
- DYSF | c.591C>T p.Y197= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs564416027, CM090599, COSV50328645, COSV50679357; called by muse, mutect2, varscan2
- F13A1 | c.1452C>T p.F484= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV53554003; called by muse, mutect2, varscan2
- FAM153A | c.465C>G p.S155= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100646880; called by mutect2, varscan2
- FAM153B | c.696C>G p.S232= (on ENST00000253490; = p.S155= on NM_001265615.1) | Silent (SNP) | VAF 44/448 reads (10%) | catalogued as COSV53686449; called by muse, mutect2
- FAM43A | c.99G>T p.S33= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100316317; called by muse, mutect2, varscan2
- FBXO46 | c.1044C>A p.P348= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV58348620, COSV58348639; called by muse, mutect2, varscan2
- FEZF1 | c.1011A>T p.I337= | Silent (SNP) | VAF 76/358 reads (21%) | catalogued as COSV58658745; called by muse, mutect2, varscan2
- GLI1 | c.2007G>T p.V669= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV57361837; called by muse, mutect2, varscan2
- GOLGA8G | c.1005C>A p.L335= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- GRM8 | c.765T>C p.R255= | Silent (SNP) | VAF 48/272 reads (18%) | catalogued as COSV58825809; called by muse, mutect2, varscan2
- HSF2 | c.468C>G p.S156= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV63773896; called by muse, mutect2, varscan2
- HTR3B | c.162C>A p.T54= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV52744598; called by muse, mutect2, varscan2
- IGKV6D-41 | c.6G>T p.V2= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- IGLON5 | c.288C>A p.S96= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV54534531, COSV54535826; called by muse, mutect2, varscan2
- IST1 | c.930A>T p.A310= (on ENST00000535424 / NM_001270976.1; = p.H296L on NM_014761.4) | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV58663433; called by muse, mutect2, varscan2
- KCNJ5 | c.1014C>T p.T338= | Silent (SNP) | VAF 58/242 reads (24%) | catalogued as COSV57966036; called by muse, mutect2, varscan2
- KCNT1 | c.1135C>A p.R379= (on ENST00000488444; = p.R398= on NM_020822.3) | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV53698283, COSV99704674; called by muse, mutect2, varscan2
- LRFN2 | c.702C>A p.P234= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100599013, COSV57825544; called by muse, mutect2, varscan2
- LRP1B | c.10722C>A p.G3574= | Silent (SNP) | VAF 71/320 reads (22%) | catalogued as COSV67219897; called by muse, varscan2
- MED24 | c.270G>A p.R90= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV62418622; called by muse, mutect2, varscan2
- MUC16 | c.19791G>T p.V6597= | Silent (SNP) | VAF 83/358 reads (23%) | catalogued as COSV67465630; called by muse, mutect2, varscan2
- MUC20 | c.1446C>A p.S482= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV57849955, COSV57851120; called by muse, varscan2
- MUC3A | c.7518C>T p.T2506= | Silent (SNP) | VAF 92/237 reads (39%) | catalogued as COSV60215782; called by muse, mutect2, varscan2
- N4BP2 | c.66T>G p.V22= | Silent (SNP) | VAF 74/285 reads (26%) | catalogued as COSV54701887; called by muse, varscan2
- NOTCH2 | c.1761T>C p.G587= | Silent (SNP) | VAF 32/359 reads (9%) | catalogued as COSV56691344; called by muse, mutect2
- OGDHL | c.1746A>T p.V582= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV65102405; called by muse, mutect2, varscan2
- OR10AG1 | c.609G>A p.L203= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV56632903; called by muse, mutect2, varscan2
- OR4C6 | c.255C>G p.S85= | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as rs757786657, COSV58603991; called by muse, mutect2, varscan2
- OR4F6 | c.669G>T p.V223= | Silent (SNP) | VAF 74/371 reads (20%) | catalogued as COSV61026773; called by muse, mutect2, varscan2
- OR5H1 | c.711C>A p.A237= | Silent (SNP) | VAF 53/255 reads (21%) | catalogued as COSV63402251; called by muse, mutect2, varscan2
- OR8B4 | c.417C>A p.V139= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV62069719; called by muse, mutect2, varscan2
- POU3F2 | c.1251G>T p.G417= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs761254912, COSV60408917; called by muse, mutect2, varscan2
- PRAMEF14 | c.1410C>A p.L470= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- PTGES2 | c.276G>T p.A92= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1217199984, COSV52968462; called by muse, mutect2
- RALBP1 | c.1959G>A p.T653= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs537354453, COSV50035357; called by muse, mutect2, varscan2
- RUFY3 | c.1017G>T p.G339= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV56913578; called by muse, mutect2, varscan2
- SERPINB12 | c.675G>C p.T225= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as COSV54033165, COSV99501624; called by muse, mutect2, varscan2
- SEZ6L | c.2058C>T p.G686= | Silent (SNP) | VAF 89/447 reads (20%) | catalogued as rs141142000; called by muse, mutect2, varscan2
- SFRP4 | c.696A>G p.R232= | Silent (SNP) | VAF 54/206 reads (26%) | catalogued as COSV71412376; called by muse, mutect2, varscan2
- SGPP2 | c.466C>T p.L156= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs772959246, COSV58329036; called by muse, mutect2, varscan2
- SLC11A2 | c.1308A>G p.S436= (on ENST00000394904 / NM_001379455.1; = p.S407= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV50370748; called by muse, mutect2, varscan2
- SLC5A11 | c.864G>A p.T288= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as rs376534051; called by muse, mutect2, varscan2
- SYT9 | c.672G>A p.L224= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV59618336; called by muse, mutect2, varscan2
- TBC1D32 | c.1926A>G p.A642= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs1326050990, COSV51543304; called by muse, mutect2, varscan2
- TECTB | c.873C>A p.T291= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV101027602; called by muse, mutect2, varscan2
- TM9SF4 | c.420G>T p.V140= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as COSV54106946; called by muse, mutect2, varscan2
- TMPRSS11F | c.411T>C p.D137= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as COSV62466489; called by muse, mutect2, varscan2
- TNFRSF13B | c.132G>T p.L44= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV55427769; called by muse, mutect2, varscan2
- TRIM49 | c.231C>T p.A77= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- TTI1 | c.1548G>C p.V516= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs544143684, COSV100989639, COSV65061636; called by muse, mutect2, varscan2
- TTN | c.27870G>A p.V9290= (on ENST00000591111; = p.V8363= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs2742338, COSV60059652; called by muse, mutect2, varscan2
- TTN | c.1176G>T p.A392= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- UACA | c.1914A>G p.S638= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as rs769394198, COSV59855778; called by muse, mutect2, varscan2
- WDR17 | c.3600T>A p.P1200= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV54574087; called by muse, varscan2
- AL353804.7 | chrX:73846782 C>A | 5'Flank (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- TTLL8 | c.1087+10C>A | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99837852; called by muse, mutect2, varscan2
- TTN | c.10361-4105T>C | Intron (SNP) | VAF 45/383 reads (12%) | catalogued as COSV59918992; called by muse, mutect2, varscan2
